Somatic mutation profile of tumor specimen BA2422D (aliquot aq-BA2422D) from BEATAML1.0 case 2449, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Myelodysplastic syndrome with isolated del (5q); Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.1 years (27,049 days).
Specimen BA2422D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e3e8806-18a8-493a-bcad-20955617c11e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2476D (Solid Tissue Normal), aliquot aq-BA2476D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0acb696d-7c3e-4db1-9c96-175742ac01a1

The open-access MAF lists 36 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, Intron 3, 5'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 55/123 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD35 | c.1295C>A p.A432E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs138067247, COSV62910804; called by muse, mutect2
- CNTNAP5 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70505946; called by muse, mutect2, varscan2
- ELMOD1 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56190577; called by muse, mutect2, varscan2
- ZNF546 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as rs770645959; called by muse, mutect2, varscan2
- ANO4 | c.92T>G p.M31R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AP1M1 | c.629_631del p.L210del | In Frame Del (DEL) | VAF 22/194 reads (11%) | called by mutect2, pindel
- FAM3B | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLYATL1 | c.605T>A p.I202K (on ENST00000317391 / NM_001354699.1; = p.I233K on NM_080661.4) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- GPA33 | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- GPC6 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 35/440 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.61); called by muse, mutect2
- ITPRIP | c.1140G>C p.W380C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- KRT83 | c.750+2T>C p.X250_splice | Splice Site (SNP) | VAF 46/211 reads (22%) | called by muse, mutect2, varscan2
- MAP1A | c.4906C>A p.Q1636K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- METAP2 | c.115A>G p.R39G | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); called by muse, mutect2
- PCOLCE2 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- POLR2B | c.2533dup p.Y845Lfs*6 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- RNF31 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.072); called by muse, mutect2
- SORBS2 | c.1682G>A p.S561N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TIMM21 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF816 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by mutect2, varscan2
- CTR9 | c.2244C>A p.P748= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs904744860; called by muse, varscan2
- EEF2K | c.528A>G p.V176= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- FAM186A | c.1731G>A p.E577= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs78724690; called by muse, mutect2, varscan2
- JPH4 | c.324G>T p.G108= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- NTNG2 | c.781C>T p.L261= | Silent (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2
- PCDH8 | c.2700C>T p.S900= | Silent (SNP) | VAF 116/280 reads (41%) | called by muse, mutect2, varscan2
- RIOK2 | c.1047G>T p.G349= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV99300260; called by muse, mutect2, varscan2
- SEZ6L | c.1521G>A p.T507= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs371509981; called by muse, mutect2, varscan2
- ST14 | c.1872C>T p.G624= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs763733922, COSV53833556; called by muse, mutect2, varscan2
- WDR45B | c.465C>T p.L155= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs1259738258; called by muse, varscan2
- C19orf12 | chr19:29699665 T>G | 3'Flank (SNP) | VAF 154/515 reads (30%) | called by muse, varscan2
- EIF2B4 | c.32-73G>T | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs919423917; called by muse, mutect2
- NUCB2 | c.1256-39A>T | Intron (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- SLC22A15 | c.-35C>A | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- UXS1 | c.1028-212G>T | Intron (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
